Gene-level copy-number profile of specimen HCM-SANG-0523-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0523-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0523-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file df5fb535-dc91-48f6-a2e3-f9ba8a94e1bf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0523-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,255 have no estimate.
https://portal.gdc.cancer.gov/files/dea109a3-22ec-494e-b0b1-60cfc98378ac

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 15; copy number 2: 7,144; copy number 3: 27,087; copy number 4: 16,889; copy number 5: 2,809; copy number 6: 4,421.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:73,567,620–73,582,918, 3 genes: ACOT2, NT5CP1, AC005225.4.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
